Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A24K, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A24K-01A (Primary Tumor).

	W 4/23/11	

Final Diagnosis

Breast; left, wide local excision: Invasive ductal carcinoma, Nottingham grade III (of III), forming a 2.7 x 2.7 x 1.5 cm mass (AJCC pT2). The margins, including the separately submitted superior margin, are negative for tumor. The closest margin (superior) is free by 1.5 cm.

Lymph nodes, left axillary sentinel, excision: Multiple (2) left axillary sentinel lymph nodes are negative for tumor [AJCCpN0 (i-sn)]. Blue dye is identified in both left axillary sentinel lymph nodes. Immunohistochemical cytokeratin stain was performed on the paraffin embedded sentinel lymph node tissue and confirms the H&E impression.

1CD-0-3

carcinoma, infiltrating duct, nos 8500/3

Site: breast, nos C50.9 W 4/25/11

Source: NCI Genomic Data Commons file 9c246efa-1faa-474d-b824-766eca7077cf (TCGA-AR-A24K.BC7B3577-CA6C-41AD-98E2-89D357D29D37.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).